Surgical pathology report (de-identified scan), TCGA case TCGA-19-1787, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1787-01B (Primary Tumor).

[REDACTED] [REDACTED] [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

FINAL DIAGNOSIS

A, B. LEFT FRONTAL LOBE OF BRAIN, CYSTIC LESION, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV) WITH GIANT CELL, GRANULAR CELL, AND
PAPILLARY DIFFERENTIATION.

Note: Immunohistochemical stains for glial antigens are positive, while those for epithelial and melanoma-related antigens are negative.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents [REDACTED] have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. Touch Imprint and Microscopic: Giant cell glioblastoma.

Clinical History:

left brain tumor

Specimens Submitted As:

A: LEFT FRONTAL CYSTIC MASS
B: LEFT BRAIN TUMOR

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name, number and "left frontal cystic mass", is a 0.5 x 0.5 x 0.4 cm irregular fragment of tan-brown, soft tissue. A touch imprint and a frozen section are performed. The tissue is submitted entirely in two cassettes.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, are multiple light tan to pink irregular soft tissue fragments measuring 3.4 x 3.0 x 0.3 cm in aggregate. The largest fragment is serially sectioned. Submitted entirely in four cassettes.

Summary of cassettes
B1 large fragment
B2-B4 remaining tissue

Source: NCI Genomic Data Commons file a3f60bb5-c43f-46b9-827a-86642cb80906 (TCGA-19-1787.BBFA055E-EFC5-4F81-971F-7BDEA4726B36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).